TCGA case TCGA-B6-A0IJ — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2c86c3ea-d926-4d39-a5ae-39ece4774287

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 42.8 years (15,625 days); Year of diagnosis: 1995; Method of diagnosis: Excisional Biopsy; AJCC pathologic T: T3; AJCC pathologic N: N0 (i-); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 27; Micrometastasis present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 5,383 days (14.7 years); Disease response: Tumor Free.
- Days to follow up: 7,106 days (19.5 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ESR1 (IHC): Positive.
- PGR (IHC): Positive.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B6-A0IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 170 mg.
  Slide TCGA-B6-A0IJ-01A-01-BSA: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 4; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-B6-A0IJ-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 3; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-B6-A0IJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B6-A0IJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Er positivity method: Image Analysis; Pr positivity define method: Image Analysis; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Indeterminate (neither Pre or Postmenopausal); Micromet detection by IHC: No; Margin status: Negative; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant; Anatomic organ subdivision: Right.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 7,106 days; disease-specific survival: no event (censored), 7,106 days; disease-free interval: no event (censored), 7,106 days; progression-free interval: no event (censored), 7,106 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B6-A0IJ-01A-11D-A036-01): tumor purity 0.4, ploidy 3.22, whole-genome doublings 1.
